HCMI case HCM-BROD-0721-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bae134d5-d971-4fff-9c92-64e399e0d3ce

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 57.7 years (21,082 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T3a; AJCC pathologic N: N2; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Neoadjuvant; Days to treatment start: 468 days (1.3 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 866 days (2.4 years); Days to treatment end: 1,258 days (3.4 years).
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C79.2; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues, NOS; Classification of tumor: metastasis; Age at diagnosis: 60.2 years (21,980 days); Days to diagnosis: 898 days (2.5 years); Satellite nodule present: Present.
   Pathology details: Breslow thickness category: >2.0-4.0 mm; Lymph nodes positive: 1; Lymph nodes tested: 15; Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.

Follow-up (2 entries)
- Days to follow up: 2,070 days (5.7 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 1,804.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 99 kg; Height: 172 cm; BMI: 33.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-0721-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0721-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 4.
